CCDI case PBCADA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/14146643-16e5-4c22-a473-4b53f6d01ece

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 17.5 years (6,377 days).

Biospecimens (3 samples)
- Sample 0DM4OI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZU1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZU6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
